Somatic mutation profile of tumor specimen TCGA-G9-6366-01A (aliquot TCGA-G9-6366-01A-11D-2114-08) from TCGA case TCGA-G9-6366, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.4 years (22,428 days).
Specimen TCGA-G9-6366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3685179a-6a93-4eba-9dba-11be50a046d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6366-10A (Blood Derived Normal), aliquot TCGA-G9-6366-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fb31dd4-f1d1-4b43-921b-4474e178bb98

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNB4 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs1319704904, COSV52391210; called by muse, mutect2, varscan2
- CALCOCO1 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.63); catalogued as rs535194693, COSV50412611; called by muse, mutect2, varscan2
- CYP27B1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57348277; called by muse, mutect2, varscan2
- EP300 | c.6262C>T p.R2088W | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201569846, COSV54329503; called by muse, mutect2, varscan2
- FAM120B | c.2282A>T p.Q761L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV53002552; called by muse, mutect2
- IGHV4-31 | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as rs1211762430; called by muse, mutect2, varscan2
- IL17RC | c.728G>A p.R243Q (on ENST00000295981 / NM_153461.4; = p.R172Q on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs771496986, COSV55967115; called by muse, mutect2
- LRFN3 | c.1130C>G p.A377G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV55817235; called by muse, mutect2, varscan2
- NINL | c.3791G>A p.R1264H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs763276747, COSV54000272, COSV54003651; called by muse, mutect2, varscan2
- NIPBL | c.4906C>G p.R1636G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as COSV56947019; called by muse, mutect2, varscan2
- NSA2 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1160142852, COSV57187777; called by muse, mutect2
- PLCZ1 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.388); catalogued as COSV56850674; called by muse, mutect2, varscan2
- PTCH2 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV64710405; called by muse, mutect2
- SACM1L | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs761208104, COSV66612811; called by muse, mutect2, varscan2
- SSH2 | c.1362C>A p.N454K | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV52168707; called by muse, mutect2
- SYNE2 | c.14707A>C p.K4903Q | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs774194914, COSV59944484; called by muse, mutect2, varscan2
- THTPA | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV55337711; called by muse, mutect2
- TSSK2 | c.564G>C p.Q188H | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52816573; called by muse, mutect2, varscan2
- TYK2 | c.2434G>T p.E812* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53385857; called by muse, mutect2, varscan2
- UACA | c.3647A>G p.K1216R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV59854370; called by muse, mutect2, varscan2
- PTEN | c.738_740del p.L247del | In Frame Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.1488G>A p.S496= | Silent (SNP) | VAF 65/189 reads (34%) | catalogued as rs1159619040, COSV50120381, COSV50174570; called by muse, mutect2, varscan2
- CNST | c.1482A>G p.G494= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV63621600; called by muse, mutect2, varscan2
- ERBB2 | c.2343T>C p.Y781= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV54066396; called by muse, mutect2, varscan2
- MYBPC1 | c.3222T>A p.P1074= (on ENST00000550270 / NM_206820.2; = p.P1081= on NM_002465.4) | Silent (SNP) | VAF 67/218 reads (31%) | catalogued as COSV62251934; called by muse, mutect2, varscan2
- PGLYRP4 | c.582C>T p.G194= | Silent (SNP) | VAF 59/199 reads (30%) | catalogued as rs536231867, COSV62834854; called by muse, mutect2, varscan2
- SAG | c.552C>T p.A184= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV68590592; called by muse, mutect2
- UHRF1BP1L | c.2287T>C p.L763= | Silent (SNP) | VAF 58/202 reads (29%) | catalogued as COSV54435706; called by muse, mutect2, varscan2
